Somatic mutation profile of tumor specimen 0DFXH6 from CCDI case PBBSKE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,606 days).
Specimen 0DFXH6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46e754dd-1ee7-453d-90e6-6203ab7b1efe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFXEW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5ea7ff2-7ffb-41e2-84ae-d2b250d13cd3

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Nonsense Mutation 1, Silent 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 336/654 reads (51%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PDGFRA | c.1973T>C p.V658A | Missense Mutation (SNP) | VAF 693/1297 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1057519812; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.902del p.P301Qfs*44 | Frame Shift Del (DEL) | VAF 382/699 reads (55%) | catalogued as rs876660726, COSV53267099, COSV53486315; ClinVar: pathogenic; called by pindel, varscan2
- BNC1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 515/1101 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61756378; called by muse, mutect2, varscan2
- DST | c.16130A>G p.N5377S (on ENST00000361203 / NM_001374722.1; = p.N2965S on NM_015548.5) | Missense Mutation (SNP) | VAF 192/606 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs762298460, COSV99758466; called by muse, mutect2, varscan2
- FRMPD2 | c.980C>G p.P327R | Missense Mutation (SNP) | VAF 213/535 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100563879, COSV59717286; called by muse, mutect2, varscan2
- SPATA46 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 190/758 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs151327006; called by muse, mutect2, varscan2
- CDC14C | c.822C>A p.F274L (on ENST00000428251; = p.F167L on NM_152627.3) | Missense Mutation (SNP) | VAF 389/1422 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- GPN1 | c.937T>G p.L313V | Missense Mutation (SNP) | VAF 207/879 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEPH | c.2374G>T p.G792C (on ENST00000343002; = p.G525C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/536 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PDGFRA | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 701/1407 reads (50%) | called by muse, mutect2
- PDGFRA | c.1086G>C p.E362D | Missense Mutation (SNP) | VAF 689/1374 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR51L1 | c.93C>A p.I31= | Silent (SNP) | VAF 20/711 reads (3%) | called by muse, mutect2
- MDM1 | c.*100C>A | 3'UTR (SNP) | VAF 16/176 reads (9%) | called by mutect2, varscan2
